MMRF case MMRF_1283 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b1295fc9-a0ce-4e60-b6d5-a28234c5b3e4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.6 years (23,943 days); ISS stage: II; Days to last known disease status: 48 days; Days to last follow up: 48 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (2 entries)
- Days to follow up: -28 days; ECOG performance status: 0.
- Follow-up contact recording only the day: day 48.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Free Immunoglobulin Light Chain, Kappa 13.3 mg/dL.
- Absolute Neutrophil 1.5 ×10⁹/L.
- Glucose 5.23 mmol/L.
- Leukocytes 3.8 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Lambda 0.29 mg/dL.
- Creatinine 79.6 µmol/L.
- Albumin 29 g/L.
- Beta 2 Microglobulin 4.17 µg/mL.
- Hemoglobin 7.13 mmol/L.
- Total Protein 9.5 g/dL.
- Platelets 238 ×10⁹/L.
- M Protein 4.2 g/dL.
- Calcium 2.13 mmol/L.
- Blood Urea Nitrogen 4.64 mmol/L.

Other clinical attributes
- Day -28: Weight: 65 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_1283_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -28 days.
- Sample MMRF_1283_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -28 days.
